Surgical pathology report (de-identified scan), TCGA case TCGA-GC-A3I6, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-GC-A3I6-01A (Primary Tumor).

[page 1 of 3]
Surg Path Final Report

* Final Report *

Result Type: Surg Path Final Report
Result Date:
Result Status:
Result Title: Surgical Pathology Final Report
Verified By:
Encounter Info:

Final Diagnosis (Verified)

Distal left ureter, frozen section examination, excision:
Negative for neoplasm.

Distal right ureter, frozen section examination, excision:
Negative for neoplasm.

Additional prostatic apical tissue:

Benign prostatic glandular tissue with scattered areas of squamous metaplasia involving the duct lumen, no invasive malignancy identified.

Radical cystoprostatectomy:

Infiltrating high-grade urothelial carcinoma with diffuse squamous differentiation extending through entire bladder muscular wall and to radial margin of surgical excision. inked

Bladder tumor measures 5.5 cm in maximum dimension and is positioned on the posterior bladder wall. Marked necrosis is present.

Prostate is negative for malignancy.

Seminal vesicles are negative.

100-0-3

Left lymph node dissection:

Seven (7) negative lymph nodes.

carcinoma, urothelial, nos 8120/3

Site: bladder, nos C67.9

Right lymph node dissection:

Four (4) negative lymph nodes.

pw 12/24/11

Printed by:
Printed on:

Page 1 of 3
(Continued)

[page 2 of 3]
Surg Path Final Report

* Final Report *

Comment: This large, partially necrotic, diffusely infiltrating, high-grade transitional cell carcinoma shows diffuse areas of squamous differentiation. The tumor extends to the inked radial margin of excision. This case corresponds to a pathological AJCC stage of T3a,N0.

Signature Line

(Electronically signed by)
Verified on:

Gross Description (Verified)

"FSA." All frozen section control tissue is submitted in cassette "FSA,".

"FSB." All frozen section control tissue is submitted in cassette "FSB,".

"C, Additional apical tissue." The specimen consists of 3 unoriented soft gray-pink fragments ranging in size from 1.6 x 1.6 x 0.7 cm to 2.4 x 1 x 0.8 cm. Inked black. "C1-C2," fragments, representative.

"D, Bladder." The specimen consists of an 11.8 x 9.5 x 6.6 cm bladder with attached fat. Attached is the prostate gland. Bilateral distal ureters have previously been submitted for frozen section. The specimen is opened on the anterior aspect and there is a 5.5 x 3.5 cm soft red-tan friable ulcerated mass on the posterior bladder wall which extends to the right aspect of the bladder. The mass grossly appears to extend into the bladder musculature to a depth of 2.5 cm and grossly appears to abut the radial margin. The radial margin has been inked black. The mass does not grossly appear to involve the left and right ureteral orifices. The remaining bladder mucosa is red-tan and edematous and no additional areas of interest are grossly identified in the bladder. The attached prostate gland measures 4.2 x 4 x 1.8 cm. The posterior apex will be inked orange. The remaining prostate is inked black. The seminal vesicles and vas deferens will be submitted at their junction with the prostate. The prostatic parenchyma is tan and no discrete yellow masses are grossly identified. "D1," distal urethral margin; "D2-D5," bladder mass with adjacent radial margin (NOTE: Cassette deeply represents 1 full-thickness section submitted in steps); "D6," mass; "D7," left bladder mucosa; "D8," bladder dome; "D9," right bladder mucosa; "D10," trigone; "D11," left seminal vesicle and vas deferens; "D12," right seminal vesicle and vas deferens; "D13," left anterior prostate; "D14," right anterior prostate; "D15," left posterior prostate; "D16," right posterior prostate.

"E, Left lymph node." The specimen consists of a 3.6 x 3.6 x 2 cm aggregate of yellow lobulated tissue. On sectioning, 7 possible lymph nodes are identified. These range in size from 0.3 to 1.5 cm. "E1-E3," fragments, representative.

"F, Right lymph node." The specimen consists of a 4.4 x 3.2 x 1.5 cm aggregate of yellow lobulated tissue. On sectioning, 4 possible lymph nodes are identified. These range in size from 0.4 to 1.8 cm. "F1-F2," fragments, representative.

Printed by:
Printed on:

Page 2 of 3
(Continued)

[page 3 of 3]
Surg Path Final Report

* Final Report *

Received for research purposes is 1 yellow cassette labeled "

Signature Line

Frozen Section Diagnosis (Verified)

FSA: Distal left ureter: No tumor noted.

FSB: Distal right ureter: No tumor noted.

Clinical Information (Verified)

This -year-old white male is a patient with spina bifida who has been on lifelong intermittent catheterizations. The patient has a long history of smoking (3 to 4 packs a day).

Completed Action List:

* Order by

* VERIFY by

* Order by

Printed by:
Printed on:

Page 3 of 3
(End of Report)

Source: NCI Genomic Data Commons file 998a527a-fe37-4f1d-abe7-deeb1bbc79bd (TCGA-GC-A3I6.FFC0F91A-AC95-4E02-BE22-EBDAE89AB5EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).